Somatic mutation profile of tumor specimen TARGET-50-PAJNTJ-02A (aliquot TARGET-50-PAJNTJ-02A-01D) from TARGET case TARGET-50-PAJNTJ, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.9 years (707 days).
Specimen TARGET-50-PAJNTJ-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ff49e0d-469c-4e68-8165-d3923daaf18e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJNTJ-10A (Blood Derived Normal), aliquot TARGET-50-PAJNTJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf1310a9-2a75-44ff-aaa4-e57bff4489b0

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF17 | c.5707G>A p.V1903M | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs140379964; called by muse, mutect2, varscan2
- CDH12 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 31/326 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as rs371189490; called by muse, mutect2, varscan2
- RUSC2 | c.3311G>A p.R1104H | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373601054; called by muse, mutect2, varscan2
- CREBBP | c.5446_5450dup p.V1818Afs*57 | Frame Shift Ins (INS) | VAF 23/57 reads (40%) | called by mutect2, pindel
- FAT3 | c.9592C>T p.Q3198* | Nonsense Mutation (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- TRPM5 | c.3204G>A p.K1068= | Silent (SNP) | VAF 36/151 reads (24%) | catalogued as rs1318034098; called by muse, mutect2, varscan2
